CCDI case PBCHUF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/7b00e93f-1415-46bc-b0a8-8f546219720b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 12.9 years (4,719 days).

Biospecimens (3 samples)
- Sample 0DSKZG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSKZM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSL08: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
